CCG case CUPP-B38N — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/734de892-0da8-4044-ba84-41e29ea82a95

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1952; Vital status: Dead; Days to death: 394 days (1.1 years); Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8140/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Gastrointestinal tract, NOS; Classification of tumor: metastasis; Age at diagnosis: 65.2 years (23,807 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic M: M1; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Stomach / Peritoneum, NOS / Pleura.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative.
2. Progression (histology not recorded by GDC). Age at diagnosis: 66.2 years (24,172 days); Year of diagnosis: 2018; Days to diagnosis: 365 days (1.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90; ECOG performance status: 1.
- Day 365 (progression): Progression or recurrence: Yes; Days to progression: 365 days (1.0 years).
- Days to follow up: 394 days (1.1 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 97 kg; Height: 165 cm; BMI: 35.6.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Smoker at Diagnosis.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B38N-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B38N-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B38N-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 35; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
